Gene-level copy-number profile of tumor specimen ALCH-AE7B-TTP1-A from ALCHEMIST case ALCH-AE7B, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.6 years (21,784 days).
Specimen ALCH-AE7B-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 39f1f3f6-184e-4fe7-888f-ea1201d101dc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE7B-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,728 have no estimate.
https://portal.gdc.cancer.gov/files/2aec2f2b-be58-4cee-bedf-56bfc77096f2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 9,182; copy number 2: 48,777; copy number 3: 879; copy number 4: 11; copy number 5: 11; copy number 6: 2; copy number 10: 3.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:149,714,781–149,734,575, 1 gene: KRBA1.
- chr7:152,445,477–152,465,549, 2 genes: CCT8L1P, LINC01003.
- chr9:136,647,872–136,660,421, 1 gene (within-gene range 0–4): AL590226.1.
- chr14:103,561,896–103,714,249, 6 genes (within-gene range 0–2): KLC1, COA8, AL139300.1, RNU4-68P, AL049840.2, AL049840.6.
- chr14:103,696,353–103,733,668, 4 genes (within-gene range 0–1): AL049840.5, XRCC3, ZFYVE21, Y_RNA.
- chr14:103,847,721–103,880,381, 3 genes (within-gene range 0–2): LINC00637, AL132712.1, AL132712.2.
- chr17:78,146,353–78,166,177, 2 genes: C17orf99, EIF5AP2.
- chr18:11,993,988–11,994,938, 1 gene (within-gene range 0–1): AP001269.1.
- chr19:41,425,359–41,428,730, 2 genes (within-gene range 0–2): AC011462.2, B3GNT8.
- chr20:450,663–450,762, 1 gene (within-gene range 0–1): Y_RNA.
- chr22:21,463,963–21,471,269, 2 genes: Metazoa_SRP, TMEM191C.
- chr22:41,174,591–41,240,931, 5 genes (within-gene range 0–1): EP300-AS1, LRRC37A14P, L3MBTL2, L3MBTL2-AS1, CHADL.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:1,009,936–1,026,898, 1 gene, copy number 10: FGFRL1.
- chr4:1,113,639–1,153,726, 3 genes, copy number 5 (within-gene range 2–5): AC092535.4, TMED11P, AC092535.1.
- chr4:1,166,932–1,208,962, 1 gene, copy number 5 (within-gene range 2–5): SPON2.
- chr4:1,210,120–1,249,953, 2 genes, copy number 5 (within-gene range 3–5): CTBP1-AS, CTBP1.
- chr11:1,223,066–1,262,172, 2 genes, copy number 6 (within-gene range 1–13): MUC5B, MUC5B-AS1.
- chr16:88,453,280–88,537,031, 1 gene, copy number 5 (within-gene range 3–6): ZFPM1.
- chr16:88,512,960–88,531,053, 1 gene, copy number 5 (within-gene range 5–6): AC116552.1.
- chr17:78,168,581–78,173,527, 1 gene, copy number 5: SYNGR2.
- chr19:8,695,721–8,698,795, 2 genes, copy number 5: AC243312.1, ACTL9.
- chr21:43,461,960–43,479,534, 2 genes, copy number 10: LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 6,364. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
